ALCHEMIST case ALCH-AE4S — Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial (ALCHEMIST-ALCH)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026).
https://portal.gdc.cancer.gov/cases/3db06ae0-2429-4d80-8602-92ce7f2eb5d2

Demographics
Sex at birth: male.

Diagnoses (1)
1. Adenocarcinoma, NOS: Age at diagnosis: 57.7 years (21,090 days).

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample ALCH-AE4S-NB1-B: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Whole Blood; Preservation method: Fresh.
- Sample ALCH-AE4S-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
  Slide ALCH-AE4S-TTP1-A-1-0-S1: Section location: Top; Percent tumor cells: 65; Percent tumor nuclei: 65; Percent normal cells: 5; Percent necrosis: 1; Percent stromal cells: 29; Percent lymphocyte infiltration: 3; Percent monocyte infiltration: 10; Percent neutrophil infiltration: 5.
- Sample ALCH-AE4S-TTR1-A: Sample type: FFPE Recurrent; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Solid Tissue; Preservation method: FFPE.
  Slide ALCH-AE4S-TTR1-A-1-0-S1: Section location: Top; Percent tumor cells: 82; Percent tumor nuclei: 55; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 18; Percent lymphocyte infiltration: 40; Percent monocyte infiltration: 2; Percent neutrophil infiltration: 0.
